Gene-level copy-number profile of tumor specimen TCGA-DX-A6BF-01A from TCGA case TCGA-DX-A6BF, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 82.3 years (30,071 days).
Specimen TCGA-DX-A6BF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.ea1edc70-c00e-4c7f-8e59-12f8d4cea0ba.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A6BF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1c59c04c-7fdd-4f8d-a73f-4b354aefbc11

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 10; copy number 2: 6,652; copy number 3: 15,392; copy number 4: 31,288; copy number 5: 2,835; copy number 6: 2,522; copy number 7: 453; copy number 8: 85; copy number 9: 59; copy number 10: 30; copy number 11: 62; copy number 12: 9; copy number 13: 69; copy number 14: 17; copy number 16: 39; copy number 17: 2; copy number 19: 13; copy number 20: 79; copy number 21: 4; copy number 22: 1; copy number 23: 46; copy number 25: 50; copy number 28: 4; copy number 32: 10; copy number 33: 3; copy number 35: 2; copy number 37: 1; copy number 38: 12; copy number 44: 21; copy number 47: 40; copy number 51: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A6BF-01A-11D-A306-01): tumor purity 0.59, ploidy 3.72, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 578 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:44,545,493–44,545,552, 1 gene, copy number 22: MIR5584.
- chr1:58,228,682–59,296,491, 20 genes, copy number 23: AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1.
- chr1:65,420,652–66,988,619, 16 genes, copy number 10–16 (within-gene range 4–16): LEPR, AC119800.1, AC097063.1, AL513493.1, RN7SL854P, PDE4B, PDE4B-AS1, RNU4-88P, SGIP1, MIR3117, AL139147.1, TCTEX1D1, INSL5, DNAI4, AL592161.1, MIER1.
- chr1:67,307,364–67,833,467, 11 genes, copy number 14 (within-gene range 5–14): IL12RB2, SERBP1, RNU6-387P, LINC01702, RNU6-1031P, AL590559.1, RN7SL392P, HNRNPCP9, GADD45A, GNG12, RNU7-80P.
- chr1:68,242,474–68,449,954, 5 genes, copy number 12 (within-gene range 4–12): RPS7P4, COX6B1P7, ELOCP18, AL139413.1, RPE65.
- chr1:170,662,728–174,022,357, 76 genes, copy number 10–20 (within-gene range 4–20) (broad region; genes not listed).
- chr5:28,548,135–28,809,291, 3 genes, copy number 33 (within-gene range 4–33): AC008825.1, AC109472.1, RNU6-909P.
- chr5:34,905,260–35,048,135, 4 genes, copy number 20: RAD1, BRIX1, DNAJC21, AGXT2.
- chr5:41,868,975–41,968,366, 8 genes, copy number 10–14: AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6.
- chr12:57,693,955–60,363,935, 53 genes, copy number 11–13: OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1.
- chr12:61,600,067–64,162,217, 46 genes, copy number 10–23 (within-gene range 3–23): DUX4L52, AC090629.1, TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP, MON2, AC079035.1, RNU6-399P, LINC01465, AC048341.1, MIRLET7I, AC048341.2, PPM1H, RPL32P26, GAPDHP44, RNU1-83P, Y_RNA, RPL14P1, AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5, AVPR1A, AC135584.1, HNRNPA1P69, AC026116.1, DPY19L2, AC084357.2, AC027667.1, AC084357.3, AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1.
- chr12:65,134,688–65,248,355, 3 genes, copy number 20: APOOP3, LEMD3, AC026124.2.
- chr12:65,281,657–65,286,728, 1 gene, copy number 20: AC026124.1.
- chr12:65,824,460–65,966,291, 4 genes, copy number 21 (within-gene range 4–21): HMGA2, AC107308.1, HMGA2-AS1, AC090673.1.
- chr12:66,563,524–67,096,410, 4 genes, copy number 12–35 (within-gene range 12–42): OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2.
- chr12:67,265,842–68,451,663, 24 genes, copy number 16 (within-gene range 4–16): GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1.
- chr12:68,746,125–70,637,440, 43 genes, copy number 28–47 (within-gene range 4–47): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1.
- chr12:70,671,918–70,672,856, 1 gene, copy number 28: FAHD2P1.
- chr12:73,648,666–74,402,600, 7 genes, copy number 17–51 (within-gene range 4–51): AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394.
- chr12:74,663,774–75,984,015, 21 genes, copy number 44 (within-gene range 3–44): AC123904.1, AC123904.3, AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1, AC078923.1, AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1, AC011611.6.
- chr12:77,775,783–77,783,576, 1 gene, copy number 37: AC138331.1.
- chr12:80,936,414–81,759,553, 7 genes, copy number 16 (within-gene range 3–16): ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1.
- chr12:85,874,295–87,802,028, 12 genes, copy number 38: NTS, MGAT4C, AC016993.1, AC139697.1, AC010196.1, AC079597.1, RPL23AP68, AC079598.4, CYCSP30, AC079598.2, MKRN9P, LINC02258.
- chr12:88,033,846–88,602,195, 10 genes, copy number 32: C12orf29, CEP290, RNA5SP364, AC091516.1, TMTC3, Y_RNA, KITLG, AC024941.2, RNU1-117P, AC024941.1.
- chr12:90,107,739–90,300,974, 2 genes, copy number 12: AC126178.1, LINC02392.
- chr12:92,702,843–93,408,146, 17 genes, copy number 13: PLEKHG7, EEA1, AC026111.1, HNRNPA1P50, RNU6-1329P, LINC02413, AC138123.1, Y_RNA, AC021646.1, RPL41P5, AC138123.2, NACAP8, LINC02412, AC126172.1, AC124947.2, AC124947.1, NUDT4.
- chr12:99,985,045–100,173,659, 8 genes, copy number 20: AC078916.1, RPS4XP1, AC126474.1, UHRF1BP1L, AC126474.2, AC010203.2, GOLGA2P5, RN7SL176P.
- chr12:100,473,708–102,513,655, 50 genes, copy number 25: NR1H4, AC010200.1, GAS2L3, PIGAP1, ANO4, AC138360.1, AC063947.1, SNX5P2, SLC5A8, RNU6-768P, AC079953.1, UTP20, ARL1, AC063948.1, RNU6-1068P, RPS27P23, Y_RNA, RNU5E-5P, RNA5SP367, SPIC, MYBPC1, AC117505.1, AC010205.1, CHPT1, RNY1P16, SYCP3, GNPTAB, RNU6-101P, AC063950.1, RNA5SP368, RNU6-172P, RNA5SP369, RNU6-1183P, HSPE1P4, DRAM1, AC084398.2, AC084398.1, AC079907.2, NENFP2, WASHC3, AC079907.1, NUP37, PARPBP, PMCH, HELLPAR, RN7SL793P, AC093023.1, LINC02456, IGF1, AC010202.1.
- chr17:78,146,353–80,100,613, 59 genes, copy number 9 (within-gene range 5–9): C17orf99, EIF5AP2, SYNGR2, TK1, AFMID, AC087645.1, BIRC5, TMEM235, AC087645.4, THA1P, AC087645.3, LINC01993, AC087645.2, SOCS3, AC061992.2, RN7SL236P, PGS1, AC061992.1, DNAH17, DNAH17-AS1, AC016182.1, RN7SL454P, SCAT1, CYTH1, AC099804.1, RNU6-638P, USP36, AC022966.2, RPL9P29, TIMP2, AC022966.1, CEP295NL, AC100788.2, AC100788.1, LGALS3BP, CANT1, C1QTNF1-AS1, C1QTNF1, ENGASE, RBFOX3, AC021534.1, AC233701.1, MIR4739, LINC02078, ENPP7, CBX2, CBX8, AC100791.2, LINC01977, CBX4, AC100791.1, LINC01979, LINC01978, TBC1D16, AC100791.3, AC116025.2, AC116025.1, CCDC40, MIR1268B.
- chr17:82,018,702–83,095,122, 61 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
